Somatic mutation profile of tumor specimen MP2PRT-PASVTK-TMP1-A (aliquot MP2PRT-PASVTK-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASVTK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (879 days).
Specimen MP2PRT-PASVTK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00f495e6-12c4-4399-8e54-1a51c470f453.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASVTK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASVTK-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fbc1e3a-a072-4f4e-820e-ff15f1bffa55

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, In Frame Del 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CALCRL | c.11A>T p.K4M | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV66476154; called by muse, mutect2, varscan2
- CARNS1 | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 401/903 reads (44%) | catalogued as rs1187714834; called by muse, mutect2, varscan2
- KIAA1549 | c.4606C>T p.R1536C | Missense Mutation (SNP) | VAF 211/468 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766618778; called by muse, mutect2, varscan2
- LGALSL | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 142/309 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as rs770942247, COSV99482519; called by muse, mutect2, varscan2
- NELL2 | c.1850C>G p.T617S | Missense Mutation (SNP) | VAF 132/280 reads (47%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ZMIZ1 | c.861_905del p.A291_A305del | In Frame Del (DEL) | VAF 175/521 reads (34%) | called by mutect2, pindel, varscan2
- SALL4 | c.594G>A p.A198= | Silent (SNP) | VAF 229/507 reads (45%) | catalogued as rs377028033; ClinVar: likely benign; called by muse, mutect2, varscan2
